Somatic mutation profile of tumor specimen TARGET-10-PARCDS-09A (aliquot TARGET-10-PARCDS-09A-01D) from TARGET case TARGET-10-PARCDS, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.4 years (4,885 days).
Specimen TARGET-10-PARCDS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79105fa4-bf60-4935-b26d-c75bd0c423c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARCDS-10A (Blood Derived Normal), aliquot TARGET-10-PARCDS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eee6a615-9afd-4f01-8e86-92807a8d72c5

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Frame Shift Ins 2, Splice Region 1, RNA 1, Silent 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>C p.Q61P | Missense Mutation (SNP) | VAF 15/50 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABRAXAS2 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs1233255087, COSV100045034; called by muse, mutect2, varscan2
- ADCY8 | c.787G>A p.G263S | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.97); PolyPhen benign (0.141); catalogued as COSV53932785; called by muse, mutect2, varscan2
- ZNF549 | c.1291dup p.R431Kfs*4 (on ENST00000376233 / NM_001199295.2; = p.R418Kfs*4 on NM_153263.2) | Frame Shift Ins (INS) | VAF 40/106 reads (38%) | catalogued as rs765848473; called by mutect2, varscan2
- ESYT3 | c.1591-6G>T | Splice Region (SNP) | VAF 20/39 reads (51%) | called by muse, mutect2, varscan2
- IGHV3-43 | chr14:106470262 GTATCT>CGC | Missense Mutation (DEL) | VAF 49/116 reads (42%) | called by pindel, varscan2*
- KMT2D | c.15600_15601insGA p.S5201Efs*43 | Frame Shift Ins (INS) | VAF 39/111 reads (35%) | called by mutect2, pindel, varscan2
- NLGN4X | c.827C>G p.A276G | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- SLC7A3 | c.832C>A p.Q278K | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NDNF | c.1398C>T p.T466= | Silent (SNP) | VAF 66/168 reads (39%) | catalogued as rs372074352; called by muse, mutect2, varscan2
- ECM2 | chr9:92493956 C>T | 3'Flank (SNP) | VAF 7/10 reads (70%) | catalogued as rs942489604; called by muse, varscan2
- EGFEM1P | n.1020C>T | RNA (SNP) | VAF 13/36 reads (36%) | catalogued as rs1235273229; called by muse, mutect2
- UBXN1 | c.290+26C>G | Intron (SNP) | VAF 48/103 reads (47%) | called by muse, mutect2, varscan2
